Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8334, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8334-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

██████ear old female with left renal mass. Left radical nephrectomy.

Specimens Submitted:

- 1: Soft tissue, para-aortic dissection superior margin, biopsy ██████
- 2: Kidney and para-aortic lymph nodes, left, radical nephrectomy (██████)
- 3: Rib, portion of ninth, segmental excision ██████
- 4: Lymph nodes, interaortacaval, excision ██████

DIAGNOSIS:

1. **Soft tissue, para-aortic dissection superior margin, biopsy** ██████
Benign fragment of ganglion and nerve.

2. **Kidney and para-aortic lymph nodes, left, radical nephrectomy** ██████
Tumor Type:
Renal cell carcinoma - Chromophobe type

Tumor Size:
Greatest diameter is 17.5 cm.

Local Invasion (for renal cortical types):
Extends through renal capsule but confined within Gerota's fascia

Renal Vein Invasion:
Not identified

Surgical Margins:
Free of tumor

Non-Neoplastic Kidney:
Unremarkable

Adrenal Gland:
Not involved

Lymph Nodes:
Free of tumor
Number of nodes examined:2

Staging for renal cell carcinoma/oncocytoma:
pT3 Tumor extends into major veins or invades the adrenal gland or perinephric tissues, but not beyond Gerota's fascia

[page 2 of 3]
3. Rib, portion of ninth, segmental excision [REDACTED]
Benign bone and bone marrow elements.

4. Lymph nodes, interaortacaval, excision [REDACTED]
Lymph Nodes:
Not involved
Number of nodes examined:4

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1) The specimen is received fresh for frozen section consultation, labeled, "Para-aortic dissection superior margin", and consists of a piece of cylindrical soft tissue measuring 1.1 x 0.3 x 0.3 cm. It contains multiple metal clips. Cut section shows rubbery red-tan appearance. The specimen is entirely frozen.

Summary of sections:
FSC – frozen section control

2) The specimen is received fresh, labeled, "Left kidney and para-aortic lymph nodes". It consists of a kidney with surrounding perirenal adipose tissue and adrenal gland weighing 1900g and measuring 21.0 x 17.0 x 7.0 cm. The specimen is bivalved revealing a large yellow-red mass with focal areas of fibrosis measuring 17.5 x 17.0 x 7.0 cm. It occupies a predominance of the kidney with only a small portion of uninvolved renal parenchyma present which measures 4.5 x 4.5 cm in maximal dimensions. Serial sectioning of the mass reveals it to extend through the renal capsule but the mass appears still encapsulated itself. The tumor is serially sectioned revealing focal areas of yellow discoloration grossly consistent with calcifications. The perirenal and peritumoral adipose tissue is serially sectioned revealing a V-shaped adrenal gland with hemorrhage measuring 4.5 x 2.5 x 0.6 cm. The adrenal gland appears grossly free of tumor. The specimen includes a portion of adipose tissue containing multiple red-tan lymph nodes ranging from 0.5 to 2.8 cm in greatest dimension. The 2.8 cm and 1.2 cm lymph node are both bisected. All identified lymph nodes are submitted for histologic evaluation. Representative portions of the tumor are submitted for [REDACTED] Representative portions of the specimen are submitted for histologic evaluation.

Summary of Sections:
HM – vascular hilar margins
KID – kidney without tumor
AD – adrenal gland
BLN – single bisected lymph node cassettes 14 and 15
LNS – additional lymph nodes
BLN – single bisected lymph node cassette 17
T – tumor

3) The specimen is received fresh, labeled, "Portion of ninth rib". It consists of a curvilinear fragment of rib measuring 15.0 cm in length x 1.0 cm in maximal diameter. The specimen is serially sectioned revealing essentially unremarkable rib. Representative sections of the specimen are submitted, pending decalcification.

[page 3 of 3]
Summary of Sections:
RIB – ninth rib

4) The specimen is received in formalin, labeled, "Interaortacaval lymph nodes". It consists of an irregularly shaped fragment of red-tan soft tissue and lymphoid tissue measuring 2.8 x 1.9 x 0.5 cm. The specimen is serially sectioned revealing multiple lymph nodes ranging from 0.6 to 1.0 cm in greatest dimension. The specimen is entirely submitted.

Summary of Sections:
LNS - lymph nodes

Summary of Sections:

Part 1: Soft tissue, para-aortic dissection superior margin, biopsy

Block	Sect. Site	PCs
1	fsc	1

Part 2: Kidney and para-aortic lymph nodes, left, radical nephrectomy

Block	Sect. Site	PCs
1	AD	1
3	BLN	3
1	HM	1
1	KID	1
1	LNS	1
10	T	10

Part 3: Rib, portion of ninth, segmental excision

Block	Sect. Site	PCs
1	RIB	1

Part 4: Lymph nodes, interaortacaval, excision

Block	Sect. Site	PCs
2	LNS	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: BENIGN NERVE AND GANGLION.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 34a8b432-1640-47f2-8c25-8e28c6f3e761 (TCGA-KL-8334.50AC65A3-8395-4DA3-B4E5-F4A2DF9414B7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).